Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8676, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8676-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]		
[REDACTED] Case ID	[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
Stomach with a tumor up to 10x12 cm in size, with invasion into the perigastric fat. Lymph nodes are dense hyperemic, up to 3 cm in size. Omentum is hyperemic.	Adenocarcinoma of the stomach, intestinal type, G-3. Invasion is into the perigastric fat. Ten examined lymph nodes of the greater and lesser curvatures demonstrated metastases. Omentum is of normal structure.	Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 3]
Comments	Formatted Path Report
Original records read pN3a.	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Antrum Tumor size: 10 x 0 x 12 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 10/10 positive for metastasis (Greater and lesser omentum 10/10) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file b40f38fb-9586-4085-b048-c2ff79bd4194 (TCGA-BR-8676.05AE128B-CA52-4FCB-9B6B-AF8B4F6F74F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).